Gene-level copy-number profile of tumor specimen HTMCP-01-20-00271-01A from CGCI case HTMCP-01-20-00271, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 29.8 years (10,872 days).
Specimen HTMCP-01-20-00271-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file defe9dcd-a8dd-42b2-9c72-633f9c0d4716.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-20-00271-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/39739160-6401-4ac5-8958-ed4d7180dd2f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 562; copy number 1: 3,747; copy number 2: 44,235; copy number 3: 9,121; copy number 4: 912; copy number 5: 34; copy number 6: 34; copy number 7: 27; copy number 8: 30; copy number 9: 24; copy number 10: 25; copy number 11: 19; copy number 12: 29; copy number 13: 20; copy number 14: 72; copy number 17: 14; copy number 22: 2.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–89,234,912, 36 genes (within-gene range 0–2): MALLP2, MIR4436A, IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29.
- chr3:60,616,822–60,732,636, 5 genes (within-gene range 0–3): AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr22:22,871,507–22,886,379, 4 genes (within-gene range 0–1): IGLV4-3, IGLV3-2, IGLV3-1, MIR5571.
- chr22:22,893,692–22,905,025, 5 genes (within-gene range 0–1): IGLJ1, IGLC1, IGLJ2, IGLC2, IGLJ3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 330 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:20,014,780–23,251,499, 49 genes, copy number 5–22: LINC02398, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1.
- chr12:61,600,067–71,586,310, 208 genes, copy number 6–17 (within-gene range 4–17) (broad region; genes not listed).
- chr12:73,648,666–77,317,234, 63 genes, copy number 8–14 (broad region; genes not listed).
- chr12:77,379,770–77,390,869, 1 gene, copy number 14: AC073591.1.
- chr15:21,980,277–22,095,857, 9 genes, copy number 7 (within-gene range 3–56): OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4.

Autosomal genes at a single copy (total copy number 1): 1,403. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
